Somatic mutation profile of tumor specimen TARGET-20-PARAFA-09A (aliquot TARGET-20-PARAFA-09A-01D) from TARGET case TARGET-20-PARAFA, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.2 years (5,204 days).
Specimen TARGET-20-PARAFA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc47e6a8-61e3-4971-8fb1-e02debacd6c6.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARAFA-14A (Bone Marrow Normal), aliquot TARGET-20-PARAFA-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8016d901-4574-41f4-bc0f-c55d49be77ba

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.863_864insCATG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 8/33 reads (24%) | catalogued as rs1554138188, COSV51544217, COSV51551832, COSV51558469, COSV51558827, COSV51561854; called by mutect2, pindel, varscan2
- BCORL1 | c.2151C>T p.Y717= | Silent (SNP) | VAF 46/226 reads (20%) | catalogued as rs749178911, COSV54389180; called by muse, mutect2, varscan2
